Somatic mutation profile of tumor specimen 0DE5R3 from CCDI case PBBPHE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,096 days).
Specimen 0DE5R3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c98b805-39f2-42dd-ac55-76f18bfa82b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE5N9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92b4b806-53b9-4083-b6b8-1d0d2b873e17

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 188/776 reads (24%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, varscan2
- ESRP1 | c.1437G>T p.M479I | Missense Mutation (SNP) | VAF 39/654 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- EVX1 | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- IRS4 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TFEC | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 206/852 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMNL1 | c.3142C>A p.R1048= | Silent (SNP) | VAF 53/433 reads (12%) | called by muse, mutect2, varscan2
